CCDI case PBCWWI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/1ce78201-cd4f-4514-8d23-713169bbb4e9

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E1UJB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1UJU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
